Somatic mutation profile of tumor specimen C3L-07123-02 (aliquot CPT0463750006) from CPTAC case C3L-07123, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.2 years (27,839 days).
Specimen C3L-07123-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d25269db-cee4-448d-9279-eda252c12b6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07123-31 (Blood Derived Normal), aliquot CPT0463860004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8e6f4b0-5162-423c-98b1-72a366c19b05

The open-access MAF lists 1,970 somatic variants for this specimen: 1,473 protein-altering or splice-affecting, 429 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,031, Silent 429, Frame Shift Del 277, Frame Shift Ins 78, Nonsense Mutation 43, Intron 34, Splice Region 15, In Frame Del 15, Splice Site 12, 5'UTR 9, 5'Flank 8, 3'UTR 8.

Variants (750 of 1,970; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7247C>T p.P2416L (on ENST00000272895 / NM_173076.3; = p.P2098L on NM_015657.3) | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764355087, COSV55958315; ClinVar: likely pathogenic; called by mutect2, varscan2
- AKT1 | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 78/281 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.664); catalogued as COSV62572266; called by mutect2, varscan2
- ALMS1 | c.11083dup p.S3695Kfs*13 | Frame Shift Ins (INS) | VAF 82/306 reads (27%) | catalogued as rs1412574975; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- BMPR1A | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 93/328 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658515, CM081185, COSV64405161; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- CPLANE1 | c.8263dup p.T2755Nfs*8 | Frame Shift Ins (INS) | VAF 65/286 reads (23%) | catalogued as rs775263897; ClinVar: pathogenic; called by mutect2, varscan2
- CREBBP | c.5837del p.P1946Hfs*30 | Frame Shift Del (DEL) | VAF 56/230 reads (24%) | catalogued as rs587783507, CD1414263; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- CYP11B1 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 74/308 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894068, CM970407, COSV52827729; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 84/385 reads (22%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EGR2 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 119/476 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs104894159, CM980599; ClinVar: pathogenic; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 74/252 reads (29%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 162/322 reads (50%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MRE11 | c.1441del p.T481Hfs*43 | Frame Shift Del (DEL) | VAF 110/384 reads (29%) | catalogued as rs747832587; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PSTPIP1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs121908130, CM020748, COSV51198632; ClinVar: pathogenic; called by mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 80/480 reads (17%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 58/196 reads (30%) | catalogued as rs771808127, COSV55113098; called by mutect2, varscan2
- ABCA1 | c.5689C>T p.R1897W | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs760768125, CM055073, COSV66063782; called by mutect2, varscan2
- ABCB1 | c.3043del p.T1015Pfs*3 | Frame Shift Del (DEL) | VAF 84/406 reads (21%) | catalogued as COSV55964223; called by pindel, varscan2
- ABCC10 | c.1489C>T p.R497W (on ENST00000372530 / NM_001198934.2; = p.R454W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs370981120; called by mutect2, varscan2
- ABCC10 | c.3248G>A p.R1083H (on ENST00000372530 / NM_001198934.2; = p.R1055H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs753888991, COSV99766525; called by mutect2, varscan2
- ABTB2 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 116/438 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as rs554984925; called by mutect2, varscan2
- ACTA1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1278723552; called by mutect2, varscan2
- ACTL9 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 118/405 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs142929347, COSV61007030; called by mutect2, varscan2
- ACTR8 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 108/426 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749439312; called by mutect2, varscan2
- ADAM2 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 110/584 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs752991137; called by mutect2, varscan2
- ADAM22 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.328); catalogued as rs754447649; called by mutect2, varscan2
- ADAM9 | c.236T>C p.I79T | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs767418357; called by mutect2, varscan2
- ADAMTS10 | c.3085C>T p.R1029C | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV99546621; called by mutect2, varscan2
- ADAMTS19 | c.1581G>A p.W527* | Nonsense Mutation (SNP) | VAF 59/286 reads (21%) | catalogued as rs1365591945; called by mutect2, varscan2
- ADAMTS20 | c.456G>A p.T152= | Splice Region (SNP) | VAF 38/138 reads (28%) | catalogued as rs572409221, COSV67129970, COSV67130694; called by mutect2, varscan2
- ADAMTS9 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774811523; called by mutect2, varscan2
- ADAMTSL2 | c.2848dup p.H950Pfs*13 | Frame Shift Ins (INS) | VAF 90/259 reads (35%) | catalogued as rs1022557002; called by mutect2, varscan2
- ADAMTSL5 | c.979del p.V327Wfs*101 | Frame Shift Del (DEL) | VAF 120/588 reads (20%) | catalogued as COSV100389290; called by pindel, varscan2
- ADGRB1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 93/450 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs773204550; called by mutect2, varscan2
- ADGRL3 | c.4066G>A p.D1356N (on ENST00000506720 / NM_001322402.2; = p.D1245N on NM_015236.6) | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as COSV72229353; called by mutect2, varscan2
- AFAP1L1 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 104/430 reads (24%) | catalogued as rs1260509573, COSV57045054; called by mutect2, varscan2
- AGBL3 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1020880226, COSV51953429; called by mutect2, varscan2
- AGPAT2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs55755415; called by mutect2, varscan2
- AJM1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 125/457 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1201231888, COSV56035715; called by mutect2, varscan2
- AKNA | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs373387890; called by mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 85/370 reads (23%) | catalogued as rs778623472, COSV56735668; called by mutect2, varscan2
- ALDH3A2 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs375910791; called by mutect2, varscan2
- ALDH7A1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs144625212; ClinVar: uncertain significance; called by mutect2, varscan2
- AMH | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 158/585 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1334490311; called by mutect2, varscan2
- AMPD2 | c.223-3del | Splice Region (DEL) | VAF 73/286 reads (26%) | catalogued as rs770280481; called by mutect2, varscan2
- AMY2A | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 83/754 reads (11%) | catalogued as rs566657194; called by mutect2, varscan2
- ANK1 | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 106/418 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs754903343; called by mutect2, varscan2
- ANK2 | c.2513C>T p.T838M | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779991081, COSV52163065; called by mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 52/202 reads (26%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKMY1 | c.2266C>T p.R756* | Nonsense Mutation (SNP) | VAF 66/233 reads (28%) | catalogued as rs371478661; called by mutect2, varscan2
- ANKMY1 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs778075994, COSV99802162; called by mutect2, varscan2
- ANKRD24 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 146/548 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs932852974; called by mutect2, varscan2
- ANKRD44 | c.2831+1G>A p.X944_splice | Splice Site (SNP) | VAF 36/144 reads (25%) | catalogued as rs771000319; called by mutect2, varscan2
- ANKRD50 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs377077898; called by mutect2, varscan2
- ANKRD60 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 120/398 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs909510573; called by mutect2, varscan2
- ANO2 | c.2442+1G>A p.X814_splice (on ENST00000356134 / NM_001278597.3; = p.X818_splice on NM_001278596.3) | Splice Site (SNP) | VAF 82/290 reads (28%) | catalogued as rs562684300; called by mutect2, varscan2
- ANO8 | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs937475858; called by mutect2, varscan2
- AOC1 | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 112/460 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV62871330; called by mutect2, varscan2
- AP5Z1 | c.1895G>A p.S632N | Missense Mutation (SNP) | VAF 98/360 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs765929934; called by mutect2, varscan2
- APEX2 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1312285758; called by mutect2, varscan2
- APOA4 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 148/490 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs751283052, COSV63360930; called by mutect2, varscan2
- ARHGAP23 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1251439105; called by mutect2, varscan2
- ARHGAP23 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as rs750856610; called by mutect2, varscan2
- ARHGEF10 | c.3739G>A p.A1247T (on ENST00000398564; = p.A1222T on NM_014629.4) | Missense Mutation (SNP) | VAF 174/794 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs576755623, COSV50644511; called by mutect2, varscan2
- ARHGEF19 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs751065816, COSV99580928; called by mutect2, varscan2
- ARID2 | c.2245A>G p.T749A | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs572825593; called by mutect2, varscan2
- ASPHD1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 90/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs768381793; called by mutect2, varscan2
- ASPM | c.7192A>G p.M2398V | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs1255379965; called by mutect2, varscan2
- ASRGL1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs370679289, COSV57124592; called by mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 48/208 reads (23%) | catalogued as rs1558707706; called by mutect2, varscan2
- ATP12A | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs757024432; called by mutect2, varscan2
- ATP12A | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs757211146; called by mutect2, varscan2
- ATP2B1 | c.2536C>T p.R846* | Nonsense Mutation (SNP) | VAF 88/358 reads (25%) | catalogued as COSV53805755, COSV53811872; called by mutect2, varscan2
- ATP2B1 | c.406+1G>A p.X136_splice | Splice Site (SNP) | VAF 34/133 reads (26%) | catalogued as COSV53807826; called by mutect2, varscan2
- ATP2C2 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 114/402 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs760347866; called by mutect2, varscan2
- ATP4B | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 120/376 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs754901792, COSV100089976; called by mutect2, varscan2
- ATP8B1 | c.2698A>G p.M900V | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1185657094; called by mutect2, varscan2
- AURKAIP1 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1475299201; called by mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 90/315 reads (29%) | catalogued as rs35951843; called by mutect2, varscan2
- BACH1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV54519973; called by mutect2, varscan2
- BAHCC1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 150/500 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1483232923; called by mutect2, varscan2
- BAZ1A | c.4226del p.R1409Kfs*11 | Frame Shift Del (DEL) | VAF 68/260 reads (26%) | catalogued as COSV62408820; called by mutect2, pindel, varscan2
- BBS7 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs766450289; called by mutect2, varscan2
- BCL11B | c.965G>A p.R322H (on ENST00000357195 / NM_001282237.2; = p.R251H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/508 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61738759; called by mutect2, varscan2
- BCL9 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371893579; called by mutect2, varscan2
- BCL9L | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 113/450 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as rs557952430; called by mutect2, varscan2
- BLMH | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 34/164 reads (21%) | catalogued as rs765998771; called by mutect2, varscan2
- BLOC1S5 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1330247481; called by mutect2, varscan2
- BMPR1A | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs876659155, CM151995; ClinVar: uncertain significance; called by mutect2, varscan2
- BMS1 | c.2963C>A p.P988Q | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996392; called by mutect2, varscan2
- BRD4 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.853); catalogued as rs1373343624, COSV54585291; called by mutect2, varscan2
- BTNL9 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 132/432 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1236973743; called by mutect2, varscan2
- C16orf74 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.768); catalogued as rs750401569; called by mutect2, varscan2
- C1orf43 | c.418C>T p.R140* (on ENST00000368521 / NM_001297718.2; = p.R106* on NM_015449.4) | Nonsense Mutation (SNP) | VAF 113/390 reads (29%) | catalogued as rs1445765778; called by mutect2, varscan2
- C20orf194 | c.2260G>A p.G754S | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41308627, COSV52706186; called by mutect2, varscan2
- C3orf20 | c.1309del p.T437Pfs*7 | Frame Shift Del (DEL) | VAF 64/235 reads (27%) | catalogued as rs757962317; called by mutect2, pindel, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 56/227 reads (25%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C4orf54 | c.990del p.G331Efs*45 | Frame Shift Del (DEL) | VAF 58/206 reads (28%) | catalogued as rs1388862189; called by mutect2, varscan2
- C6orf132 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1321277113, COSV59375727; called by mutect2, varscan2
- C8A | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395940773, COSV63483355; called by mutect2, varscan2
- C8orf89 | c.457dup p.S153Kfs*24 | Frame Shift Ins (INS) | VAF 70/393 reads (18%) | catalogued as rs951061763; called by mutect2, varscan2
- C9orf131 | c.2521del p.H841Tfs*50 | Frame Shift Del (DEL) | VAF 131/482 reads (27%) | catalogued as COSV56612281; called by mutect2, pindel, varscan2
- CACNA1C | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100218328; called by mutect2, varscan2
- CACNA1I | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as rs377452504; called by mutect2, varscan2
- CACNA1I | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 148/515 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1281702569; called by mutect2, varscan2
- CACNG8 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1329657506, COSV54413991; called by mutect2, varscan2
- CAPN15 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 103/405 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99562496; called by mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 82/270 reads (30%) | catalogued as rs762770988, COSV62756627; called by mutect2, varscan2
- CARMIL1 | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1457601371; called by mutect2, varscan2
- CASP4 | c.236T>C p.I79T | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs1383831902; called by mutect2, varscan2
- CCAR1 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV56274243; called by mutect2, varscan2
- CCDC17 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755808620, COSV59645828, COSV59648582; called by mutect2, varscan2
- CCDC173 | c.771del p.K257Nfs*2 | Frame Shift Del (DEL) | VAF 60/244 reads (25%) | catalogued as rs760164089; called by mutect2, pindel, varscan2
- CCDC182 | c.64del p.M22* | Frame Shift Del (DEL) | VAF 95/404 reads (24%) | catalogued as rs1567992795; called by mutect2, pindel, varscan2
- CCDC191 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs144461478; called by mutect2, varscan2
- CDCA4 | c.602del p.G201Vfs*46 | Frame Shift Del (DEL) | VAF 134/424 reads (32%) | catalogued as COSV60315065; called by mutect2, varscan2
- CDH11 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 124/400 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745457288, COSV51775913; called by mutect2, varscan2
- CDK5RAP2 | c.5174G>A p.R1725H | Missense Mutation (SNP) | VAF 122/412 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs948437328, COSV62573418; called by mutect2, varscan2
- CEACAM5 | c.1802dup p.D602Rfs*19 | Frame Shift Ins (INS) | VAF 56/270 reads (21%) | catalogued as rs782698410; called by mutect2, varscan2
- CENPC | c.2573T>C p.V858A | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56621580; called by mutect2, varscan2
- CENPT | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs779684299, COSV54650304, COSV54650752, COSV99535160; called by mutect2, varscan2
- CEP131 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 152/544 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs376095607; called by mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 53/204 reads (26%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CFAP251 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 54/368 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs150940900; called by mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 152/618 reads (25%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CHD1 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763854534; called by mutect2, varscan2
- CHD3 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1156237135, COSV104398937; called by mutect2, varscan2
- CHEK1 | c.700dup p.I234Nfs*11 | Frame Shift Ins (INS) | VAF 43/150 reads (29%) | catalogued as rs1565368022; called by mutect2, varscan2
- CHL1 | c.1519G>A p.A507T (on ENST00000397491 / NM_001253387.1; = p.A523T on NM_006614.4) | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV56604520; called by mutect2, varscan2
- CHMP6 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs202074825; called by mutect2, varscan2
- CHRDL2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs146453433; called by mutect2, varscan2
- CKAP5 | c.4445G>A p.R1482Q | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1280546778; called by mutect2, varscan2
- CKAP5 | c.3313C>T p.P1105S | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56365441; called by mutect2, varscan2
- CKB | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV100818966; called by mutect2, varscan2
- CLASP1 | c.3692dup p.S1232* | Frame Shift Ins (INS) | VAF 69/254 reads (27%) | catalogued as rs749719822; called by mutect2, varscan2
- CLCN4 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs750952479, COSV66467119; called by mutect2, varscan2
- CLCN4 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 154/518 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1374813094, COSV66465074; called by mutect2, varscan2
- CLCNKA | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs552991562; called by mutect2, varscan2
- CLDN10 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs201757379, COSV100971181; called by mutect2, varscan2
- CLIP3 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 127/446 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV100859350; called by mutect2, varscan2
- CLIP3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs752645258, COSV62112721; called by mutect2, varscan2
- CLRN2 | c.435C>T p.G145= | Splice Region (SNP) | VAF 62/264 reads (23%) | catalogued as rs994079252; called by mutect2, varscan2
- CMTM3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 114/400 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.106); catalogued as rs1313149008; called by mutect2, varscan2
- CNGA2 | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 146/498 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs1183569188; called by mutect2, varscan2
- CNTN1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs779551448; called by mutect2, varscan2
- CNTN1 | c.2981G>A p.G994D | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1174104877; called by mutect2, varscan2
- COG7 | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.387); catalogued as rs765513149, COSV100207881; called by mutect2, varscan2
- COL23A1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 106/405 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66788648; called by mutect2, varscan2
- COMP | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM030027, CM120445, COSV99721640; called by mutect2, varscan2
- CPSF1 | c.4138G>A p.A1380T | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1304420700; called by mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 74/313 reads (24%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CREB3L4 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs371608503; called by mutect2, varscan2
- CRMP1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 98/378 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs548835481, COSV100271702; called by mutect2, varscan2
- CRNKL1 | c.2290_2292del p.E764del | In Frame Del (DEL) | VAF 78/400 reads (20%) | catalogued as rs757426818; called by pindel, varscan2
- CSMD3 | c.8216G>A p.C2739Y | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1213569635; called by mutect2, varscan2
- CSTF3 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60611638; called by mutect2, varscan2
- CTTNBP2NL | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 103/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1481017205; called by mutect2, varscan2
- CYP21A2 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.325); catalogued as rs1230437249; called by mutect2, varscan2
- CYP2C9 | c.295A>C p.I99L | Missense Mutation (SNP) | VAF 94/318 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs750662900; called by mutect2, varscan2
- CYP2C9 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 94/315 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs763302345; called by mutect2, varscan2
- CYTH4 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs371162850; called by mutect2, varscan2
- DCAF12L2 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 114/469 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63584239; called by mutect2, varscan2
- DDB1 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.298); catalogued as COSV57104114; called by mutect2, varscan2
- DDR2 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV63372598; called by mutect2, varscan2
- DDX24 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 144/509 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1460975526, COSV58212430; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 46/159 reads (29%) | catalogued as rs772416332; called by mutect2, varscan2
- DEDD2 | c.458dup p.T154Nfs*38 | Frame Shift Ins (INS) | VAF 70/318 reads (22%) | catalogued as rs758890887; called by mutect2, varscan2
- DENND4A | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370432277; called by mutect2, varscan2
- DENND6B | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs773433892; called by mutect2, varscan2
- DENND6B | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201514629, COSV69808144; called by mutect2, varscan2
- DES | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 144/524 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV64660597; called by mutect2, varscan2
- DHRS3 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757291841, COSV66108384; called by mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 51/221 reads (23%) | catalogued as rs373108427; called by mutect2, varscan2
- DIAPH3 | c.3402G>T p.K1134N | Missense Mutation (SNP) | VAF 98/426 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV64967573; called by mutect2, varscan2
- DIDO1 | c.6397C>T p.R2133W | Missense Mutation (SNP) | VAF 109/450 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99825613; called by mutect2, varscan2
- DIDO1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 143/474 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs201760843; called by mutect2, varscan2
- DISP3 | c.3796C>A p.L1266M | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV99037562; called by mutect2, varscan2
- DMBT1 | c.5510G>A p.R1837H (on ENST00000338354 / NM_001377530.1; = p.R1080H on NM_004406.3) | Missense Mutation (SNP) | VAF 131/495 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs748198152, COSV57537993; called by mutect2, varscan2
- DMD | c.4181C>T p.A1394V | Missense Mutation (SNP) | VAF 100/375 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV63740909; called by mutect2, varscan2
- DMD | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs398123911, COSV63733958; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- DNAH2 | c.8521G>A p.E2841K | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331012521; called by mutect2, varscan2
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 52/261 reads (20%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- DNHD1 | c.13706G>C p.G4569A | Missense Mutation (SNP) | VAF 108/411 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV54429656; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 74/218 reads (34%) | catalogued as rs782552436; called by mutect2, varscan2
- DPP6 | c.1996G>T p.G666C (on ENST00000377770 / NM_001364500.2; = p.G604C on NM_001936.5) | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167715239, COSV59604647; called by mutect2, varscan2
- DRP2 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 136/500 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1005595951; called by mutect2, varscan2
- DUS3L | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 146/478 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs758799429, COSV57831522; called by mutect2, varscan2
- DVL1 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs532164937; called by mutect2, varscan2
- DYRK2 | c.1591C>T p.R531W (on ENST00000344096 / NM_006482.3; = p.R458W on NM_003583.4) | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867420742; called by mutect2, varscan2
- EEF2 | c.2417G>A p.G806D | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58579452; called by mutect2, varscan2
- EFNA2 | c.366del p.P123Rfs*44 | Frame Shift Del (DEL) | VAF 131/491 reads (27%) | catalogued as rs1555759452; called by mutect2, pindel, varscan2
- EFR3B | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 70/504 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.617); catalogued as rs1194664981; called by mutect2, varscan2
- EGFL6 | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63633775; called by mutect2, varscan2
- EIF3A | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs201828136, COSV64963950; called by mutect2, varscan2
- ELFN2 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 145/500 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1014197650; called by mutect2, varscan2
- ELFN2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 126/415 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs759330097, COSV68745751; called by mutect2, varscan2
- EMC10 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 143/480 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as rs757880262; called by mutect2, varscan2
- EMILIN2 | c.508del p.V170* | Frame Shift Del (DEL) | VAF 110/354 reads (31%) | catalogued as rs1281163907; called by mutect2, varscan2
- ENO3 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV52777923; called by mutect2, varscan2
- ENO4 | c.1759del p.Y587Tfs*31 (on ENST00000622726; = p.Y584Tfs*31 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 70/272 reads (26%) | catalogued as rs763733545, COSV53387848; called by mutect2, varscan2
- EOMES | c.995dup p.K333Qfs*11 | Frame Shift Ins (INS) | VAF 112/460 reads (24%) | catalogued as rs1309565164; called by pindel, varscan2
- EPHA2 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 102/348 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs778319091; called by mutect2, varscan2
- EPHA5 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56639694; called by mutect2, varscan2
- ERBB3 | c.4025C>T p.T1342M | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs140679673; called by mutect2, varscan2
- ESRP2 | c.818T>C p.V273A (on ENST00000565858 / NM_001365264.1; = p.V263A on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/364 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV52172229; called by mutect2, varscan2
- EXOSC9 | c.944T>C p.I315T | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs770629761, COSV99697096; called by mutect2, varscan2
- EXT1 | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 120/487 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV100983749, COSV65485255; called by mutect2, varscan2
- F10 | c.508T>C p.Y170H | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1397114559; called by mutect2, varscan2
- FAM160A2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 117/398 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs147077635, COSV56412899; called by mutect2, varscan2
- FAM187A | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777819510; called by mutect2, varscan2
- FAM200B | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1042398618, COSV69959682; called by mutect2, varscan2
- FAM200B | c.1163G>A p.W388* | Nonsense Mutation (SNP) | VAF 75/212 reads (35%) | catalogued as rs936192228; called by mutect2, varscan2
- FAM241B | c.49del p.R17Efs*2 | Frame Shift Del (DEL) | VAF 89/408 reads (22%) | catalogued as rs746144154; called by mutect2, pindel, varscan2
- FAM71C | c.408del p.K136Nfs*5 | Frame Shift Del (DEL) | VAF 98/434 reads (23%) | catalogued as rs762930877; called by mutect2, pindel, varscan2
- FANCD2OS | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs141930678; called by mutect2, varscan2
- FANCI | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.398); catalogued as rs143105092; ClinVar: uncertain significance; called by mutect2, varscan2
- FARP2 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs372605073; called by mutect2, varscan2
- FAT1 | c.6080G>A p.R2027H | Missense Mutation (SNP) | VAF 92/414 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs745765579, COSV71674714; called by mutect2, varscan2
- FBXW8 | c.363G>A p.A121= (on ENST00000309909; = p.A159= on NM_012174.1) | Splice Region (SNP) | VAF 68/251 reads (27%) | catalogued as rs1158700124; called by mutect2, varscan2
- FCER1A | c.262A>G p.S88G | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as rs1255992158; called by mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 35/121 reads (29%) | catalogued as rs768979093, COSV55110370; called by mutect2, varscan2
- FGD5 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as rs372788718; called by mutect2, varscan2
- FGFR4 | c.1913A>G p.H638R | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs768319803; called by mutect2, varscan2
- FHIT | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 80/349 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1376237498, COSV59288167; called by mutect2, varscan2
- FMNL2 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 52/423 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as rs1367663865; called by mutect2, varscan2
- FOCAD | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 76/314 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.094); catalogued as rs140273318; called by mutect2, varscan2
- FOXA2 | c.904G>A p.E302K (on ENST00000377115 / NM_153675.3; = p.E308K on NM_021784.5) | Missense Mutation (SNP) | VAF 122/442 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.316); catalogued as rs1167689596; called by mutect2, varscan2
- FOXF2 | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.088); catalogued as rs1365776037; called by mutect2, varscan2
- FOXM1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100700887; called by mutect2, varscan2
- FPR1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs764370052, COSV59050822; called by mutect2, varscan2
- FRMD3 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.674); catalogued as rs1255438500; called by mutect2, varscan2
- FRMD4B | c.1842del p.K615Sfs*129 | Frame Shift Del (DEL) | VAF 95/436 reads (22%) | catalogued as rs1345170188; called by mutect2, pindel, varscan2
- FRMPD3 | c.4277G>A p.R1426H | Missense Mutation (SNP) | VAF 73/461 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs749892155; called by mutect2, varscan2
- FRY | c.8858G>A p.R2953H | Missense Mutation (SNP) | VAF 111/452 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs141662577; called by mutect2, varscan2
- FRYL | c.8726T>C p.I2909T | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as rs540689433; called by mutect2, varscan2
- FRYL | c.6982A>G p.T2328A | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1305185627; called by mutect2, varscan2
- FSTL4 | c.2107A>G p.S703G | Missense Mutation (SNP) | VAF 140/486 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV54766151; called by mutect2, varscan2
- FTCD | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs368825821; called by mutect2, varscan2
- FYCO1 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 119/423 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs200646936, COSV99945422; called by mutect2, varscan2
- GAK | c.3475C>T p.R1159W | Missense Mutation (SNP) | VAF 110/403 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781056821; called by mutect2, varscan2
- GALM | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229797646, COSV55370377; called by mutect2, varscan2
- GALNT12 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs775040546; called by mutect2, varscan2
- GAREM2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV68225979; called by mutect2, varscan2
- GATA3 | c.732del p.T245Pfs*20 | Frame Shift Del (DEL) | VAF 67/490 reads (14%) | catalogued as COSV60518762, COSV60521588; called by mutect2, pindel, varscan2
- GCC2 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs761805619; called by mutect2, varscan2
- GCKR | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1558434378; called by mutect2, varscan2
- GCSAM | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368331750; called by mutect2, varscan2
- GFOD1 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 105/375 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373777103; called by mutect2, varscan2
- GLB1L2 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs149988613; called by mutect2, varscan2
- GLI3 | c.3848G>A p.S1283N | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs781471350; called by mutect2, varscan2
- GLI3 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as rs146556791; ClinVar: benign; called by mutect2, varscan2
- GLT6D1 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV65627383; called by mutect2, varscan2
- GLUD2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 124/466 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs200880803, COSV60151559, COSV60152177; called by mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 146/309 reads (47%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGA4 | c.3583dup p.S1195Kfs*2 | Frame Shift Ins (INS) | VAF 82/329 reads (25%) | catalogued as rs1372475895; called by mutect2, pindel, varscan2
- GPR1 | c.380del p.F127Sfs*2 | Frame Shift Del (DEL) | VAF 110/482 reads (23%) | catalogued as rs759796967; called by mutect2, pindel, varscan2
- GPR149 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 126/498 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs763187151; called by mutect2, varscan2
- GPR18 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs778649813, COSV100540543; called by mutect2, varscan2
- GPR6 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 112/478 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51572726; called by mutect2, varscan2
- GPR62 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 132/468 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.267); catalogued as rs942595263; called by mutect2, varscan2
- GPR84 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as rs139990475; called by mutect2, varscan2
- GPRIN1 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 100/480 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1418718477; called by mutect2, varscan2
- GPRIN1 | c.171del p.R58Gfs*78 | Frame Shift Del (DEL) | VAF 103/460 reads (22%) | catalogued as rs765009644; called by mutect2, pindel, varscan2
- GREB1 | c.5773C>T p.R1925W | Missense Mutation (SNP) | VAF 104/375 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755838573, COSV52179636; called by mutect2, varscan2
- GRIN2C | c.3073G>C p.A1025P | Missense Mutation (SNP) | VAF 154/530 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.228); catalogued as COSV53114754; called by mutect2, varscan2
- GRIN3B | c.65dup p.H23Pfs*207 | Frame Shift Ins (INS) | VAF 56/171 reads (33%) | catalogued as rs1410710745; called by mutect2, varscan2
- GRIP1 | c.1634G>A p.R545Q (on ENST00000359742 / NM_001379345.1; = p.R493Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs370175362; called by mutect2, varscan2
- GRM2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 117/419 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770473805; called by mutect2, varscan2
- GRM4 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs537259785; called by mutect2, varscan2
- GSC | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 135/467 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99450046; called by mutect2, varscan2
- GTF2IRD2B | c.2823G>T p.W941C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100441312; called by mutect2, varscan2
- GYS1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs933420343, COSV54402838; called by mutect2, varscan2
- GZMB | c.382A>G p.R128G | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1360620278; called by mutect2, varscan2
- H3C3 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1376372933, COSV63550920; called by mutect2, varscan2
- H3C8 | c.411G>C p.*137Yext*29 | Nonstop Mutation (SNP) | VAF 47/152 reads (31%) | catalogued as rs767426202, COSV59953139; called by mutect2, varscan2
- HCN4 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763669122, COSV56081172; called by mutect2, varscan2
- HECW1 | c.1768A>G p.T590A | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV67842578; called by mutect2, varscan2
- HECW2 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs763718773; called by mutect2, varscan2
- HFM1 | c.4163del p.N1388Tfs*37 | Frame Shift Del (DEL) | VAF 46/214 reads (21%) | catalogued as rs759278255; called by mutect2, pindel, varscan2
- HMCN1 | c.7738G>T p.G2580C | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99638158; called by mutect2, varscan2
- HOXB5 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs373035488; called by mutect2, varscan2
- HOXD13 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 118/408 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs1325737834; called by mutect2, varscan2
- HS6ST2 | c.882del p.E295Sfs*18 | Frame Shift Del (DEL) | VAF 129/507 reads (25%) | catalogued as COSV63716261; called by mutect2, pindel, varscan2
- HSPA2 | c.1864A>G p.S622G | Missense Mutation (SNP) | VAF 98/378 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1566643513, COSV55968677; called by mutect2, varscan2
- HSPBAP1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV100063594; called by mutect2, varscan2
- HTT | c.8869C>T p.R2957W | Missense Mutation (SNP) | VAF 114/354 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1560607858; called by mutect2, varscan2
- ID1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs768929678; called by mutect2, varscan2
- ID2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 116/414 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52170565; called by mutect2, varscan2
- IDI1 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.038); catalogued as rs1383068648; called by mutect2, varscan2
- IGHV3-66 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.196); catalogued as rs1405991255; called by mutect2, varscan2
- IGSF10 | c.5789T>C p.V1930A | Missense Mutation (SNP) | VAF 96/390 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1008998514; called by mutect2, varscan2
- IL1RL2 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.467); catalogued as rs72998581, COSV51816341; called by mutect2, varscan2
- IL21R | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 130/426 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); catalogued as rs774786859, COSV100560627; called by mutect2, varscan2
- IL21R | c.1460T>C p.M487T | Missense Mutation (SNP) | VAF 112/460 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs757464564; called by mutect2, varscan2
- ILDR2 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1260382900, COSV54833566; called by mutect2, varscan2
- IMMT | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 101/394 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs751732579; called by mutect2, varscan2
- INPP4A | c.2401G>A p.V801M (on ENST00000074304 / NM_001134224.1; = p.V762M on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253335546; called by mutect2, varscan2
- IQANK1 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 128/621 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as rs1374400195; called by mutect2, varscan2
- IQGAP2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as rs572815114, COSV99167125; called by mutect2, varscan2
- IRS1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 137/437 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1295643078, COSV100524840; called by mutect2, varscan2
- ISLR2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 143/479 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1428568162; called by mutect2, varscan2
- ITGA11 | c.3520C>T p.R1174C | Missense Mutation (SNP) | VAF 84/354 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1378685868, COSV59875216; called by mutect2, varscan2
- ITGA5 | c.167del p.P56Rfs*114 | Frame Shift Del (DEL) | VAF 109/504 reads (22%) | catalogued as COSV53219246; called by mutect2, pindel, varscan2
- ITGAE | c.1801del p.L601Wfs*82 | Frame Shift Del (DEL) | VAF 130/503 reads (26%) | catalogued as rs867709180; called by mutect2, pindel, varscan2
- ITIH4 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 126/376 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373017674; called by mutect2, varscan2
- ITPR3 | c.5566G>A p.E1856K | Missense Mutation (SNP) | VAF 122/412 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1470806540, COSV65405691; called by mutect2, varscan2
- JPH2 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs540933939; called by mutect2, varscan2
- KALRN | c.5326C>T p.R1776C (on ENST00000360013 / NM_001024660.4; = p.R79C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/474 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1241849175, COSV52254081; called by mutect2, varscan2
- KAT6B | c.4406C>T p.S1469L | Missense Mutation (SNP) | VAF 132/412 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.651); catalogued as rs773808647, COSV99768563; called by mutect2, varscan2
- KCNAB1 | c.1049G>A p.R350H (on ENST00000490337 / NM_172160.3; = p.R339H on NM_003471.3) | Missense Mutation (SNP) | VAF 68/311 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs758644631; called by mutect2, varscan2
- KCND1 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 124/511 reads (24%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.017); catalogued as rs879962772; called by mutect2, varscan2
- KCNK17 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747130965, COSV64685589; called by mutect2, varscan2
- KIAA0319 | c.394del p.D132Tfs*10 | Frame Shift Del (DEL) | VAF 116/478 reads (24%) | catalogued as rs745716096, COSV65497875; called by mutect2, pindel, varscan2
- KIAA1191 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs753140539; called by mutect2, varscan2
- KIF17 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs372872118; called by mutect2, varscan2
- KIF4B | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 142/522 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762854775; called by mutect2, varscan2
- KIFC3 | c.1966C>T p.R656* | Nonsense Mutation (SNP) | VAF 86/312 reads (28%) | catalogued as rs782402093, COSV65550099; called by mutect2, varscan2
- KIRREL2 | c.1953dup p.C652Lfs*49 | Frame Shift Ins (INS) | VAF 75/379 reads (20%) | catalogued as rs761116739; called by mutect2, varscan2
- KMT2D | c.12547C>T p.Q4183* | Nonsense Mutation (SNP) | VAF 109/468 reads (23%) | catalogued as COSV99983504; called by mutect2, varscan2
- KMT2D | c.8689G>T p.G2897C | Missense Mutation (SNP) | VAF 103/368 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV56490506; called by mutect2, varscan2
- KMT2D | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 78/309 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs747892077; called by mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 42/156 reads (27%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT19 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs533516685, COSV64239312; called by mutect2, varscan2
- KRT28 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100137679; called by mutect2, varscan2
- KRT35 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 151/527 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs1368806460; called by mutect2, varscan2
- KRT71 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as rs1394956135, COSV57289517; called by mutect2, varscan2
- KRTAP12-3 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100555102; called by mutect2, varscan2
- LAMA5 | c.1556C>A p.P519H | Missense Mutation (SNP) | VAF 144/468 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs749283348, COSV53369516; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 123/295 reads (42%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LGALS9 | c.1037del p.G346Afs*5 (on ENST00000395473 / NM_009587.3; = p.G314Afs*5 on NM_002308.4) | Frame Shift Del (DEL) | VAF 108/473 reads (23%) | catalogued as rs775745717; called by mutect2, pindel, varscan2
- LHFPL4 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 93/310 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753941704; called by mutect2, varscan2
- LPCAT1 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV52039521; called by mutect2, varscan2
- LPP | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57086965; called by mutect2, varscan2
- LRRC14 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 101/563 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs577816867, COSV52880162; called by mutect2, varscan2
- LRRC42 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs775217051; called by mutect2, varscan2
- LRRD1 | c.724dup p.Y242Lfs*2 | Frame Shift Ins (INS) | VAF 38/169 reads (22%) | catalogued as rs904187040; called by mutect2, varscan2
- LTF | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs1253218659, COSV51606145; called by mutect2, varscan2
- LTN1 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.106); catalogued as rs374171789; called by mutect2, varscan2
- LY75 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 128/480 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs760516310, COSV55101767, COSV55109549; called by mutect2, varscan2
- LYST | c.2290C>T p.H764Y | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765210466; called by mutect2, varscan2
- MADD | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1195327978, COSV100211611; called by mutect2, varscan2
- MAGEE1 | c.1652T>C p.L551P | Missense Mutation (SNP) | VAF 118/469 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100819199, COSV63910080, COSV63912447; called by mutect2, varscan2
- MANBA | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs763126091, COSV99898990; called by mutect2, varscan2
- MAP4 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as rs765950415; called by mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 64/198 reads (32%) | catalogued as rs761388884; called by mutect2, pindel, varscan2
- MAPK8IP3 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373591543; called by mutect2, varscan2
- MCF2 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.533); catalogued as rs759504777, COSV58496545; called by mutect2, varscan2
- MCM3 | c.1733T>C p.M578T (on ENST00000229854 / NM_001366374.2; = p.M568T on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs374635915; called by mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 48/185 reads (26%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MED12L | c.5054C>A p.P1685H | Missense Mutation (SNP) | VAF 66/337 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56389710; called by mutect2, varscan2
- MED29 | c.170C>T p.A57V (on ENST00000615911; = p.A36V on NM_017592.4) | Missense Mutation (SNP) | VAF 128/466 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV55395661; called by mutect2, varscan2
- MEGF6 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs764681187, COSV99619990; called by mutect2, varscan2
- MELTF | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs759104120; called by mutect2, varscan2
- METTL22 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 148/454 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs770562473; called by mutect2, varscan2
- MGAT1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 134/456 reads (29%) | PolyPhen benign (0.006); catalogued as rs985736712; called by mutect2, varscan2
- MICALL2 | c.1284dup p.G429Rfs*61 | Frame Shift Ins (INS) | VAF 134/475 reads (28%) | catalogued as rs751396826; called by mutect2, pindel, varscan2
- MICU2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138030448; called by mutect2, varscan2
- MICU3 | c.803del p.N268Mfs*47 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | catalogued as rs199759760; called by mutect2, varscan2
- MIGA2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs761137509; called by mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | catalogued as rs751180035; called by mutect2, varscan2
- MMEL1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs755571656; called by mutect2, varscan2
- MMP13 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs767829684, COSV52823318; called by mutect2, varscan2
- MMP15 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 130/476 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs539694635; called by mutect2, varscan2
- MN1 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 138/492 reads (28%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.024); catalogued as rs756370849; called by mutect2, varscan2
- MOK | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 117/416 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766520450; called by mutect2, varscan2
- MPHOSPH10 | c.2007_2009del p.K670del | In Frame Del (DEL) | VAF 32/148 reads (22%) | catalogued as rs771691850; called by pindel, varscan2
- MPL | c.1848C>A p.C616* | Nonsense Mutation (SNP) | VAF 112/393 reads (28%) | catalogued as COSV65244636; called by mutect2, varscan2
- MPPED2 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV63897432, COSV99050185; called by mutect2, varscan2
- MSX2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 102/366 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756030049; called by mutect2, varscan2
- MTA2 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as rs775798480; called by mutect2, varscan2
- MTHFD2L | c.1033dup p.I345Nfs*10 (on ENST00000395759 / NM_001144978.2; = p.I287Nfs*10 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 56/197 reads (28%) | catalogued as rs761538540; called by mutect2, varscan2
- MUC2 | c.2299G>A p.V767I | Missense Mutation (SNP) | VAF 106/388 reads (27%) | SIFT tolerated (0.83); catalogued as rs746618932; called by mutect2, varscan2
- MUC5B | c.13743del p.S4582Pfs*56 | Frame Shift Del (DEL) | VAF 178/759 reads (23%) | catalogued as COSV71594247; called by mutect2, pindel, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 230/401 reads (57%) | catalogued as rs764857791; called by mutect2, varscan2
- MYCBP2 | c.13093G>A p.E4365K (on ENST00000357337; = p.E4403K on NM_015057.5) | Missense Mutation (SNP) | VAF 113/358 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62015083; called by mutect2, varscan2
- MYH3 | c.5536C>T p.R1846W | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757418855, COSV56863601; called by mutect2, varscan2
- MYLK | c.3536C>T p.A1179V | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs189757903; called by mutect2, varscan2
- MYLPF | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1166607170, COSV58442786; called by mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 94/330 reads (28%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO1C | c.496C>T p.R166C (on ENST00000648651 / NM_001080779.2; = p.R131C on NM_033375.5) | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs769587880, COSV62999081; called by mutect2, varscan2
- MYO3A | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as rs773997906; ClinVar: uncertain significance; called by mutect2, varscan2
- MYO6 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs753090524; called by mutect2, varscan2
- MYO7B | c.3998G>A p.R1333Q | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539849422; called by mutect2, varscan2
- N4BP3 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs772298001, COSV51070384; called by mutect2, varscan2
- NACAD | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 158/584 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs946455316; called by mutect2, varscan2
- NACC1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs777031740, COSV52835995; called by mutect2, varscan2
- NAT8L | c.225dup p.R76Afs*30 | Frame Shift Ins (INS) | VAF 28/170 reads (16%) | catalogued as rs1394359135; called by mutect2, varscan2
- NAV2 | c.1811C>T p.A604V (on ENST00000396087 / NM_001244963.2; = p.A581V on NM_145117.5) | Missense Mutation (SNP) | VAF 130/465 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs773836305; called by mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 66/236 reads (28%) | catalogued as rs763376147; called by mutect2, varscan2
- NCAPG2 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs758069657; called by mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 104/350 reads (30%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NDUFA10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 104/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771783427; called by mutect2, varscan2
- NEB | c.12438del p.K4146Nfs*6 | Frame Shift Del (DEL) | VAF 38/205 reads (19%) | catalogued as COSV50808793; called by mutect2, pindel, varscan2
- NEK1 | c.2556del p.V853Yfs*8 | Frame Shift Del (DEL) | VAF 54/216 reads (25%) | catalogued as rs760894879; called by mutect2, varscan2
- NEURL1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1296058393; called by mutect2, varscan2
- NEXN | c.196_197dup p.W67Nfs*25 | Frame Shift Ins (INS) | VAF 46/214 reads (21%) | catalogued as rs750492151; called by mutect2, varscan2
- NFATC4 | c.74del p.P25Rfs*69 | Frame Shift Del (DEL) | VAF 65/320 reads (20%) | catalogued as rs778613456; called by mutect2, pindel, varscan2
- NIN | c.5264C>T p.A1755V (on ENST00000382041 / NM_182946.1; = p.A1042V on NM_016350.4) | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs758555048, COSV55389524; ClinVar: uncertain significance; called by mutect2, varscan2
- NKD1 | c.862del p.R288Afs*59 | Frame Shift Del (DEL) | VAF 115/448 reads (26%) | catalogued as rs772439983; called by mutect2, pindel, varscan2
- NKX2-3 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV60728422; called by mutect2, varscan2
- NKX3-2 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs762376522; called by mutect2, varscan2
- NLRP5 | c.2842G>A p.V948I | Missense Mutation (SNP) | VAF 109/360 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768814118, COSV66766874; called by mutect2, varscan2
- NME6 | c.322C>T p.R108C (on ENST00000415053; = p.R116C on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/487 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs762940733, COSV56640636; called by mutect2, varscan2
- NMRK1 | c.536del p.L179Cfs*7 | Frame Shift Del (DEL) | VAF 63/276 reads (23%) | catalogued as COSV100738050; called by mutect2, pindel, varscan2
- NOD1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 124/494 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.357); catalogued as rs766935307; called by mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 140/554 reads (25%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH1 | c.3685G>A p.V1229I | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs766198119, COSV53103948; called by mutect2, varscan2
- NOTCH2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.914); catalogued as rs782563564; called by mutect2, varscan2
- NOTUM | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 94/363 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as rs751311735, COSV68825922; called by mutect2, varscan2
- NPBWR2 | c.487dup p.A163Gfs*159 | Frame Shift Ins (INS) | VAF 158/656 reads (24%) | catalogued as rs757434354; called by mutect2, pindel, varscan2
- NPS | c.244del p.T82Lfs*10 | Frame Shift Del (DEL) | VAF 82/363 reads (23%) | catalogued as rs1455620486; called by mutect2, pindel, varscan2
- NPY2R | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs755838016, COSV61527886, COSV61528318; called by mutect2, varscan2
- NRCAM | c.3035G>A p.R1012Q (on ENST00000379028 / NM_001371124.1; = p.R996Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs752010098; called by mutect2, varscan2
- NRXN2 | c.3539G>A p.R1180Q | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs763626243, COSV55449381; called by mutect2, varscan2
- NTN1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 116/392 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV51481235; called by mutect2, varscan2
- NTN3 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1015795471; called by mutect2, varscan2
- NTNG2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 120/420 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1254592166, COSV62364098; called by mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 90/368 reads (24%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 48/252 reads (19%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NUTM2B | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 46/372 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1229037447; called by mutect2, varscan2
- NYNRIN | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 132/500 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749094268, COSV66844036; called by mutect2, varscan2
- OBSL1 | c.2557G>A p.V853M | Missense Mutation (SNP) | VAF 141/576 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs374405158; called by mutect2, varscan2
- OCA2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 130/430 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1566803455; called by mutect2, varscan2
- ODF2 | c.62C>T p.T21M (on ENST00000434106 / NM_153433.2; = p.T65M on NM_153432.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.796); catalogued as rs371327851; called by mutect2, varscan2
- ONECUT2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 106/361 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs954601926, COSV72152977; called by mutect2, varscan2
- OR10H2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.052); catalogued as COSV59945744; called by mutect2, varscan2
- OR4K14 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 116/408 reads (28%) | catalogued as rs867798282, COSV59292112; called by mutect2, varscan2
- OR4N2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs777854313, COSV100270101, COSV60050696; called by mutect2, varscan2
- OR52H1 | c.590A>C p.N197T (on ENST00000322653; = p.N203T on NM_001005289.1) | Missense Mutation (SNP) | VAF 114/372 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754410738, COSV100497276; called by mutect2, varscan2
- OR5M10 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 118/382 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV101595932; called by mutect2, varscan2
- OR5M3 | c.896T>C p.M299T | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs748236820; called by mutect2, varscan2
- ORC3 | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV57643879; called by mutect2, varscan2
- OTOG | c.7051G>A p.V2351M | Missense Mutation (SNP) | VAF 108/426 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745715097, COSV61133762; called by mutect2, varscan2
- OTOP2 | c.41del p.P14Rfs*24 | Frame Shift Del (DEL) | VAF 136/521 reads (26%) | catalogued as rs1038793108; called by mutect2, pindel, varscan2
- P2RX3 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771408677; called by mutect2, varscan2
- PADI1 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as rs531986952; called by mutect2, varscan2
- PALM3 | c.1016G>A p.G339E (on ENST00000340790; = p.G354E on NM_001145028.2) | Missense Mutation (SNP) | VAF 127/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1387001566; called by mutect2, varscan2
- PANK1 | c.1468G>T p.G490* | Nonsense Mutation (SNP) | VAF 74/312 reads (24%) | catalogued as COSV56810456; called by mutect2, varscan2
- PANK2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1483678197, COSV57256448; called by mutect2, varscan2
- PAPPA2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 122/434 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100866766; called by mutect2, varscan2
- PARD3B | c.2509dup p.T837Nfs*25 (on ENST00000406610 / NM_001302769.2; = p.T768Nfs*25 on NM_057177.7) | Frame Shift Ins (INS) | VAF 78/345 reads (23%) | catalogued as rs772816756; called by mutect2, varscan2
- PARP10 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 98/550 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs781999070, COSV57296906, COSV57299465; called by mutect2, varscan2
- PAWR | c.705_707del p.E235del | In Frame Del (DEL) | VAF 46/194 reads (24%) | catalogued as rs753546988; called by pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 113/444 reads (25%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PAX6 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM068272, CM078153; called by mutect2, varscan2
- PCDH10 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 140/510 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs752073353; called by mutect2, varscan2
- PCDH11X | c.3899C>T p.A1300V | Missense Mutation (SNP) | VAF 110/452 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs768077489; called by mutect2, varscan2
- PCDH17 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 137/451 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64978045; called by mutect2, varscan2
- PCDHA1 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 115/387 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as COSV65372858; called by mutect2, varscan2
- PCDHA12 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.025); catalogued as COSV56482640, COSV99165190; called by mutect2, varscan2
- PCDHAC1 | c.202del p.V68Wfs*28 | Frame Shift Del (DEL) | VAF 108/430 reads (25%) | catalogued as COSV53852042; called by mutect2, pindel, varscan2
- PCDHB10 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 112/453 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.247); catalogued as rs782027926; called by mutect2, varscan2
- PCDHB2 | c.223del p.M75Cfs*14 | Frame Shift Del (DEL) | VAF 121/454 reads (27%) | catalogued as rs782086614; called by mutect2, varscan2
- PCDHB6 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 126/514 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782020721; called by mutect2, varscan2
- PCDHB6 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 162/656 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.772); catalogued as rs149770310, COSV50715368; called by mutect2, varscan2
- PCDHB8 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 109/477 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50770066, COSV99177047; called by mutect2, varscan2
- PCDHGA7 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 126/419 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.063); catalogued as COSV53939826; called by mutect2, varscan2
- PCDHGA7 | c.2314del p.Q772Sfs*5 | Frame Shift Del (DEL) | VAF 96/391 reads (25%) | catalogued as COSV53950889; called by mutect2, pindel, varscan2
- PCK2 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 66/416 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs146891790, COSV99394000; called by mutect2, varscan2
- PCNT | c.7223C>T p.A2408V | Missense Mutation (SNP) | VAF 103/390 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as rs754616596; called by mutect2, varscan2
- PCNX1 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs537998725, COSV53097086; called by mutect2, varscan2
- PCP2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537729714; called by mutect2, varscan2
- PDE1B | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs371717266; called by mutect2, varscan2
- PDE4DIP | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs199736417; called by mutect2, varscan2
- PDE9A | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs139833833; called by mutect2, varscan2
- PDS5B | c.3592del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 34/265 reads (13%) | catalogued as rs755801132, COSV59734300; called by mutect2, pindel, varscan2
- PDZD8 | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1390076508, COSV53692314; called by mutect2, varscan2
- PDZRN4 | c.395del p.G132Afs*96 | Frame Shift Del (DEL) | VAF 40/196 reads (20%) | catalogued as rs1203008747; called by mutect2, pindel, varscan2
- PGR | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867516411, COSV99677268; called by mutect2, varscan2
- PHF2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63679046; called by mutect2, varscan2
- PHF20L1 | c.508-1G>T p.X170_splice | Splice Site (SNP) | VAF 69/284 reads (24%) | catalogued as COSV55189876; called by mutect2, varscan2
- PHLPP1 | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 118/426 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs569551998, COSV53022621; called by mutect2, varscan2
- PI4KA | c.5180C>T p.A1727V | Missense Mutation (SNP) | VAF 105/326 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55411301; called by mutect2, varscan2
- PIAS1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs778533264; called by mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 46/236 reads (19%) | catalogued as rs925772654; called by mutect2, pindel, varscan2
- PIEZO1 | c.6056G>A p.R2019H | Missense Mutation (SNP) | VAF 135/431 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747845025; called by mutect2, varscan2
- PIEZO1 | c.5281C>T p.R1761W | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs766289450; called by mutect2, varscan2
- PIGA | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 104/452 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs769061128; ClinVar: uncertain significance / benign; called by mutect2, varscan2
- PIGP | c.166G>A p.V56M (on ENST00000464265 / NM_153681.2; = p.V6M on NM_016430.4) | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs374872366; called by mutect2, varscan2
- PIK3CA | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as rs748197872, COSV55943795; ClinVar: uncertain significance; called by mutect2, varscan2
- PIK3CB | c.1773T>C p.L591= | Splice Region (SNP) | VAF 54/230 reads (23%) | catalogued as COSV100005310; called by mutect2, varscan2
- PIK3R2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 104/373 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1440570627; called by mutect2, varscan2
- PIMREG | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 126/391 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs752671456, COSV51470712; called by mutect2, varscan2
- PITPNC1 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 66/300 reads (22%) | catalogued as COSV55458305; called by mutect2, varscan2
- PITPNM2 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 122/422 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54900233; called by mutect2, varscan2
- PIWIL2 | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs372146015; called by mutect2, varscan2
- PKD1L1 | c.8222A>C p.Q2741P | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as rs567473804; called by mutect2, varscan2
- PKN1 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs549209369; called by mutect2, varscan2
- PLCG1 | c.3802G>A p.A1268T (on ENST00000373271 / NM_182811.2; = p.A1269T on NM_002660.3) | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs761191435, COSV54820536; called by mutect2, varscan2
- PLCH2 | c.4184C>T p.A1395V | Missense Mutation (SNP) | VAF 124/468 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs372493621; called by mutect2, varscan2
- PLCXD3 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs541277706, COSV60603980; called by mutect2, varscan2
- PLEC | c.13147C>T p.R4383C (on ENST00000322810 / NM_201380.4; = p.R4273C on NM_000445.5) | Missense Mutation (SNP) | VAF 132/580 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782080936; called by mutect2, varscan2
- PLEC | c.10655C>T p.A3552V (on ENST00000322810 / NM_201380.4; = p.A3442V on NM_000445.5) | Missense Mutation (SNP) | VAF 114/598 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs201343829; ClinVar: uncertain significance; called by mutect2, varscan2
- PLEKHG6 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748865560, COSV99164181; called by mutect2, varscan2
- PLEKHH3 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 117/346 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1324785594, COSV52218461; called by mutect2, varscan2
- PLRG1 | c.1485+1G>A p.X495_splice | Splice Site (SNP) | VAF 48/174 reads (28%) | catalogued as rs1345871669, COSV57424047; called by mutect2, varscan2
- PLSCR3 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 118/422 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1174093729, COSV61171235; called by mutect2, varscan2
- PLXNA1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 139/478 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1199026244, COSV99302394; called by mutect2, varscan2
- PLXNA2 | c.2887C>T p.R963* | Nonsense Mutation (SNP) | VAF 86/304 reads (28%) | catalogued as rs148394446; called by mutect2, varscan2
- PLXNA2 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 140/448 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773351580; called by mutect2, varscan2
- PLXNA3 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 90/346 reads (26%) | catalogued as COSV63755438; called by mutect2, varscan2
- PMFBP1 | c.2971A>G p.M991V (on ENST00000537465; = p.M986V on NM_031293.3) | Missense Mutation (SNP) | VAF 128/538 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1357437736; called by mutect2, varscan2
- PNLIPRP3 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs570400848; called by mutect2, varscan2
- PNN | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs756793100, COSV53766548, COSV99397465; called by mutect2, varscan2
- POLD1 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70958279; called by mutect2, varscan2
- POTEC | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 80/518 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs201849570; called by mutect2, varscan2
- PPFIBP2 | c.2250C>T p.I750= | Splice Region (SNP) | VAF 70/212 reads (33%) | catalogued as COSV55074372; called by mutect2, varscan2
- PPID | c.683del p.N228Tfs*23 | Frame Shift Del (DEL) | VAF 15/125 reads (12%) | catalogued as rs1386625884; called by mutect2, pindel, varscan2
- PPP1R13L | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 130/492 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV62908308, COSV62908436; called by mutect2, varscan2
- PPP1R13L | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 134/494 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62909815; called by mutect2, varscan2
- PPP1R16A | c.1333del p.H445Tfs*15 | Frame Shift Del (DEL) | VAF 167/808 reads (21%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PPP1R3G | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 138/481 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs753284455; called by mutect2, varscan2
- PPP1R9B | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 82/398 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs756899491, COSV57541129; called by mutect2, varscan2
- PPRC1 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 151/511 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.541); catalogued as rs370268673; called by mutect2, varscan2
- PRAM1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 289/499 reads (58%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as rs757251739; called by mutect2, varscan2
- PRF1 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 136/480 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201909472, CM060437; ClinVar: uncertain significance; called by mutect2, varscan2
- PRKAR2B | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 108/422 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs1436699482; called by mutect2, varscan2
- PRKCG | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV54732754, COSV54733455; called by mutect2, varscan2
- PROP1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 156/528 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745650009, COSV57644616; called by mutect2, varscan2
- PRRG1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs375470626, COSV66157221; called by mutect2, varscan2
- PTCHD3 | c.1764del p.F588Lfs*18 | Frame Shift Del (DEL) | VAF 253/539 reads (47%) | catalogued as rs1448522271; called by mutect2, pindel, varscan2
- PTCHD3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 123/436 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as rs762103687, COSV71256468; called by mutect2, varscan2
- PTH1R | c.426C>T p.G142= | Splice Region (SNP) | VAF 60/238 reads (25%) | catalogued as COSV57316626; called by mutect2, varscan2
- PTPN23 | c.3299G>A p.R1100H | Missense Mutation (SNP) | VAF 146/540 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs763130796; called by mutect2, varscan2
- PTPRS | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs755739102, COSV53637098; called by mutect2, varscan2
- PTPRU | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1271200096; called by mutect2, varscan2
- PUM3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 91/393 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs758633890, COSV67395685, COSV67396654; called by mutect2, varscan2
- PXDNL | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 130/542 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759582960, COSV99080550; called by mutect2, varscan2
- PYGM | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs767293977, COSV99377392; called by mutect2, varscan2
- PZP | c.2900del p.N967Ifs*27 | Frame Shift Del (DEL) | VAF 53/266 reads (20%) | catalogued as COSV54357196; called by pindel, varscan2
- QARS1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.358); catalogued as rs371204910, COSV60276745; called by mutect2, varscan2
- RAB33A | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 154/492 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57063371; called by mutect2, varscan2
- RABEP2 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 58/215 reads (27%) | catalogued as COSV62869806; called by mutect2, varscan2
- RABGGTA | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 130/460 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1250278664; called by mutect2, varscan2
- RABL2A | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1291283384; called by mutect2, varscan2
- RAI1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 148/470 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.091); catalogued as rs1299372537; called by mutect2, varscan2
- RAPGEF3 | c.2623G>A p.E875K (on ENST00000389212; = p.E833K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as rs767541828; called by mutect2, varscan2
- RAPGEF4 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1279726029; called by mutect2, varscan2
- RASA1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs746430799, COSV57195210; called by mutect2, varscan2
- RASA2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759141778, COSV53937672; called by mutect2, varscan2
- RBKS | c.511G>T p.G171* | Nonsense Mutation (SNP) | VAF 60/240 reads (25%) | catalogued as COSV56224694; called by mutect2, varscan2
- RBM33 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV56630095; called by mutect2, varscan2
- RBMXL2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 133/449 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs1441385521; called by mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 162/520 reads (31%) | catalogued as rs759247453; called by mutect2, varscan2
- RETREG3 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148776284; called by mutect2, varscan2
- RGS9 | c.151A>T p.T51S | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as COSV52228492; called by mutect2, varscan2
- RIN1 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs200953331, COSV100254514; called by mutect2, varscan2
- RIN1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 132/482 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753952789; called by mutect2, varscan2
- RIPK1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 140/481 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs749942420, COSV99454804; called by mutect2, varscan2
- RNF31 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 106/365 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs752398891; called by mutect2, varscan2
- RNF44 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs898466469; called by mutect2, varscan2
- ROBO1 | c.2779G>A p.G927R | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs554464464; called by mutect2, varscan2
- ROBO2 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as rs760217591, COSV59942087; called by mutect2, varscan2
- ROBO3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 175/512 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1055336193; called by mutect2, varscan2
- RPTOR | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1299432885; called by mutect2, varscan2
- RRAGA | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65844130; called by mutect2, varscan2
- RRP12 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 92/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs748542158, COSV59667862; called by mutect2, varscan2
- RTL1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 116/397 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1336563358; called by mutect2, varscan2
- RTL3 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 145/493 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.012); catalogued as rs1211744950; called by mutect2, varscan2
- RTL6 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs1390705685, COSV57980353; called by mutect2, varscan2
- RTN2 | c.178del p.R60Gfs*3 | Frame Shift Del (DEL) | VAF 138/496 reads (28%) | catalogued as COSV55595576; called by mutect2, pindel, varscan2
- RYR3 | c.10445G>A p.R3482Q (on ENST00000389232; = p.R3483Q on NM_001036.6) | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763289467, COSV101213085, COSV66789758; called by mutect2, varscan2
- S1PR5 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 123/409 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV61013292; called by mutect2, varscan2
- SACS | c.3138G>T p.Q1046H | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66536199; called by mutect2, varscan2
- SAGE1 | c.2389G>T p.D797Y | Missense Mutation (SNP) | VAF 136/504 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61019073; called by mutect2, varscan2
- SALL3 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 138/495 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs750676508; called by mutect2, varscan2
- SCAMP3 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 122/403 reads (30%) | catalogued as rs1355670993; called by mutect2, varscan2
- SCAMP4 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 102/331 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs749249246; called by mutect2, varscan2
- SCN2A | c.4509dup p.L1504Tfs*15 | Frame Shift Ins (INS) | VAF 58/225 reads (26%) | catalogued as rs1396246898; called by mutect2, pindel, varscan2
- SCN3A | c.1883C>A p.A628D | Missense Mutation (SNP) | VAF 78/374 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV51816963; called by mutect2, varscan2
- SEC24A | c.1486T>A p.Y496N | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59749458; called by mutect2, varscan2
- SELENOM | c.378del p.E127Sfs*? | Frame Shift Del (DEL) | VAF 126/513 reads (25%) | catalogued as rs770782057; called by mutect2, pindel, varscan2
- SERINC5 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs775731137, COSV72595570; called by mutect2, varscan2
- SERPINE2 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs368930499; called by mutect2, varscan2
- SERPINF1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781059865, COSV99628795; called by mutect2, varscan2
- SERPINI2 | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.275); catalogued as rs761370451, COSV52988863; called by mutect2, varscan2
- SETD2 | c.4185A>T p.K1395N | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV100338723; called by mutect2, varscan2
- SETD2 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs375514539; called by mutect2, varscan2
- SETX | c.15_17del p.C5del | In Frame Del (DEL) | VAF 55/256 reads (21%) | catalogued as rs774123592; called by pindel, varscan2
- SFRP1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 106/486 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV55173682; called by mutect2, varscan2
- SH3BP1 | c.1735del p.Q579Rfs*79 | Frame Shift Del (DEL) | VAF 70/248 reads (28%) | catalogued as rs70950549; called by mutect2, pindel, varscan2
- SHANK3 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 88/293 reads (30%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.83); catalogued as rs1368172348; called by mutect2, varscan2
- SHC2 | c.599del p.K200Rfs*21 | Frame Shift Del (DEL) | VAF 78/315 reads (25%) | catalogued as COSV99077876; called by mutect2, pindel, varscan2
- SHCBP1 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as rs1220132313; called by mutect2, varscan2
- SHROOM4 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs781806295; called by mutect2, varscan2
- SIDT1 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.762); catalogued as rs765720554; called by mutect2, varscan2
- SIGIRR | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs757008588; called by mutect2, varscan2
- SIMC1 | c.2534T>G p.V845G (on ENST00000443967 / NM_001308196.1; = p.V430G on NM_198567.5) | Missense Mutation (SNP) | VAF 114/369 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53799015; called by mutect2, varscan2
- SIPA1L1 | c.5164G>A p.A1722T | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as rs1032164656; called by mutect2, varscan2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 50/225 reads (22%) | catalogued as rs1419151341, COSV66797187; called by mutect2, pindel, varscan2
- SLC12A3 | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs748994629; called by mutect2, varscan2
- SLC12A5 | c.1417G>A p.V473I (on ENST00000454036 / NM_001134771.2; = p.V450I on NM_020708.5) | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.166); catalogued as rs745565201, COSV54794432, COSV54798971; ClinVar: uncertain significance; called by mutect2, varscan2
- SLC12A7 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 114/393 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs372556472; called by mutect2, varscan2
- SLC13A3 | c.418A>G p.M140V | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs964615403; called by mutect2, varscan2
- SLC13A4 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100647315; called by mutect2, varscan2
- SLC22A16 | c.1694C>T p.T565M | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs757260946, COSV57934754; called by mutect2, varscan2
- SLC23A1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 88/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868427359, COSV100811899; called by mutect2, varscan2
- SLC2A9 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 114/427 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs756028086; called by mutect2, varscan2
- SLC36A3 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 142/483 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.416); catalogued as rs150493934; called by mutect2, varscan2
- SLC39A4 | c.28_33del p.G10_L11del | In Frame Del (DEL) | VAF 106/485 reads (22%) | catalogued as rs1564711885; called by mutect2, pindel, varscan2
- SLC43A1 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 96/378 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs146346481, COSV99561062; called by mutect2, varscan2
- SLC45A4 | c.1648G>A p.A550T (on ENST00000517878 / NM_001286646.2; = p.A499T on NM_001080431.2) | Missense Mutation (SNP) | VAF 74/370 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs542881539; called by mutect2, varscan2
- SLC5A3 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs774287970, COSV62972791; called by mutect2, varscan2
- SLF1 | c.1278T>A p.F426L | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as COSV54369815; called by mutect2, varscan2
- SLIT1 | c.4346C>T p.S1449L | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs763526147; called by mutect2, varscan2
- SLIT3 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as rs138307962; called by mutect2, varscan2
- SMARCA2 | c.985A>G p.S329G | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs774784509; called by mutect2, varscan2
- SMARCC2 | c.3583del p.L1195Cfs*88 | Frame Shift Del (DEL) | VAF 97/428 reads (23%) | catalogued as rs1224281535; called by mutect2, pindel, varscan2
- SMC2 | c.535dup p.I179Nfs*13 | Frame Shift Ins (INS) | VAF 44/196 reads (22%) | catalogued as rs1190851291; called by mutect2, varscan2
- SNTG2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as rs751591068; called by mutect2, varscan2
- SOD3 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 125/427 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs759845036; called by mutect2, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 121/438 reads (28%) | catalogued as rs778091058, COSV100846885; called by mutect2, varscan2
- SORBS1 | c.766C>T p.R256C (on ENST00000361941 / NM_001034954.2; = p.R224C on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as rs761335103, COSV99528071; called by mutect2, varscan2
- SOX11 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs758958162; called by mutect2, varscan2
- SPAG16 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 102/434 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs752948963; called by mutect2, varscan2
- SPATA18 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772456267, COSV54651114; called by mutect2, varscan2
- SPATC1 | c.790del p.Q264Sfs*152 | Frame Shift Del (DEL) | VAF 133/623 reads (21%) | catalogued as rs782200741; called by pindel, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 152/298 reads (51%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEG | c.3704G>A p.R1235H | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs769359524; called by mutect2, varscan2
- SPEM3 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 136/439 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs529514144; called by mutect2, varscan2
- SPIRE1 | c.1583C>T p.T528M (on ENST00000409402 / NM_001128626.2; = p.T514M on NM_020148.3) | Missense Mutation (SNP) | VAF 118/426 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs141286455; called by mutect2, varscan2
- SPPL2B | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 89/444 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53116292; called by mutect2, varscan2
- SPTBN4 | c.313del p.E105Sfs*26 | Frame Shift Del (DEL) | VAF 84/313 reads (27%) | catalogued as COSV58951079; called by mutect2, pindel, varscan2
- SPTBN5 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as rs371599322; called by mutect2, varscan2
- SRMS | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 138/516 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs201050342; called by mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 80/305 reads (26%) | catalogued as rs763130641; called by pindel, varscan2
- SRRM1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.924); catalogued as rs1209875188; called by mutect2, varscan2
- SSBP2 | c.152del p.N51Tfs*54 | Frame Shift Del (DEL) | VAF 82/263 reads (31%) | catalogued as rs1057518330; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- STARD9 | c.6395C>T p.A2132V | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1236922606, COSV51900328; called by mutect2, varscan2
- STAT2 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs747223187, COSV58475279; called by mutect2, varscan2
- STAU2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1216382578; called by mutect2, varscan2
- SVEP1 | c.3299C>T p.A1100V | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1358867899, COSV100238061; called by mutect2, varscan2
- SYNPO2L | c.73dup p.A25Gfs*11 | Frame Shift Ins (INS) | VAF 84/334 reads (25%) | catalogued as rs759367320; called by mutect2, varscan2
- SZT2 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 118/395 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs956294850; called by mutect2, varscan2
- SZT2 | c.5390C>T p.A1797V (on ENST00000634258 / NM_001365999.1; = p.A1740V on NM_015284.4) | Missense Mutation (SNP) | VAF 136/408 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201307513; ClinVar: uncertain significance; called by mutect2, varscan2
- SZT2 | c.8630G>A p.R2877H (on ENST00000634258 / NM_001365999.1; = p.R2820H on NM_015284.4) | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as rs923505488, COSV65173307; called by mutect2, varscan2
- TAF3 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs559757182; called by mutect2, varscan2
- TARBP2 | c.432dup p.M145Hfs*13 (on ENST00000266987 / NM_134323.2; = p.M124Hfs*13 on NM_004178.4) | Frame Shift Ins (INS) | VAF 99/406 reads (24%) | catalogued as rs750181498; called by mutect2, varscan2
- TBC1D31 | c.1585C>T p.H529Y | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs756099623; called by mutect2, varscan2
- TBCC | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 115/400 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1562442352, COSV99773975; called by mutect2, varscan2
- TBCD | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 171/562 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs774219082; called by mutect2, varscan2
- TBX2 | c.1674G>A p.M558I | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53599053; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 74/294 reads (25%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM4 | c.8084G>A p.R2695Q | Missense Mutation (SNP) | VAF 144/514 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1349164696, COSV99573279; called by mutect2, varscan2
- TEX45 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs760666310, COSV64462893; called by mutect2, varscan2
- TGIF2LX | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 150/574 reads (26%) | catalogued as COSV52215203; called by mutect2, varscan2
- THSD7B | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99743519; called by mutect2, varscan2
- TICAM1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 110/448 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs779772992, COSV50232540; called by mutect2, varscan2
- TIGD4 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs757895789; called by mutect2, varscan2
- TKTL1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 130/469 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99473742; called by mutect2, varscan2
- TLCD1 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 82/342 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as rs767094705; called by mutect2, varscan2
- TLE3 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 99/395 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs750276840, COSV58168838; called by mutect2, varscan2
- TLN2 | c.5758C>T p.R1920C | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs745389212, COSV60888251; called by mutect2, varscan2
- TMEM102 | c.462del p.I155Sfs*9 | Frame Shift Del (DEL) | VAF 105/481 reads (22%) | catalogued as COSV53439080; called by mutect2, pindel, varscan2
- TMEM160 | c.401dup p.A135Rfs*46 | Frame Shift Ins (INS) | VAF 126/498 reads (25%) | catalogued as rs954767051; called by mutect2, varscan2
- TMEM163 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 86/344 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1011399603, COSV56103907; called by mutect2, varscan2
- TMEM175 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 118/664 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs150555073; called by mutect2, varscan2
- TMEM41A | c.467del p.F156Sfs*5 | Frame Shift Del (DEL) | VAF 99/356 reads (28%) | catalogued as rs758476632; called by mutect2, varscan2
- TMEM67 | c.1550A>G p.H517R | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1350613306; called by mutect2, varscan2
- TMIE | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs763690714; called by mutect2, varscan2
- TMX3 | c.1130T>G p.M377R | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV100218352; called by mutect2, varscan2
- TNRC18 | c.2788G>A p.A930T | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1054776166; called by mutect2, varscan2
- TNRC6C | c.122del p.G41Efs*14 | Frame Shift Del (DEL) | VAF 101/465 reads (22%) | catalogued as COSV100050715; called by mutect2, pindel, varscan2
- TOGARAM2 | c.2935G>A p.V979I | Missense Mutation (SNP) | VAF 128/410 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.468); catalogued as rs370197998; called by mutect2, varscan2
- TOR4A | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62627163; called by mutect2, varscan2
- TP53BP1 | c.5765C>T p.T1922M | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs137879443, COSV104378026, COSV53018852; called by mutect2, varscan2
- TPPP3 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 149/504 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs749976048; called by mutect2, varscan2
- TPSG1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 152/516 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs1397237003, COSV52354288; called by mutect2, varscan2
- TRAK2 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs1209040214, COSV60271065; called by mutect2, varscan2
- TRAM1L1 | c.36del p.V13Ffs*128 | Frame Shift Del (DEL) | VAF 83/297 reads (28%) | catalogued as rs753182240; called by mutect2, pindel, varscan2
- TRAPPC10 | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs764930393, COSV99379381; called by mutect2, varscan2
- TRAPPC8 | c.1173del p.K391Nfs*16 | Frame Shift Del (DEL) | VAF 63/281 reads (22%) | catalogued as rs1390346780; called by mutect2, pindel, varscan2
- TRAPPC8 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs1269852922, COSV51977732, COSV99351865; called by mutect2, varscan2
- TRIM23 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 108/426 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV99139954; called by mutect2, varscan2
- TRIM39 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 172/424 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.386); catalogued as rs1474816612, COSV64956327; called by mutect2, varscan2
- TRIM65 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs750895177, COSV99485471; called by mutect2, varscan2
- TRIM66 | c.2891dup p.A965Sfs*6 | Frame Shift Ins (INS) | VAF 87/379 reads (23%) | catalogued as rs1244853823; called by mutect2, pindel, varscan2
- TRIM67 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs778976146, COSV100792120, COSV64160671; called by mutect2, varscan2
- TRIOBP | c.4436del p.G1479Afs*28 | Frame Shift Del (DEL) | VAF 176/598 reads (29%) | catalogued as rs756145453; called by mutect2, pindel, varscan2
- TRPM1 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 167/593 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1164095601; called by mutect2, varscan2
- TRPM2 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749957248, COSV55967986; called by mutect2, varscan2
- TSPAN14 | c.493A>G p.N165D | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55420272; called by mutect2, varscan2
- TSPAN17 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 93/384 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.422); catalogued as rs778619468; called by mutect2, varscan2
- TSSK2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 80/326 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs144966098; called by mutect2, varscan2
- TTC39A | c.901G>A p.E301K (on ENST00000447632 / NM_001297665.1; = p.E266K on NM_001080494.3) | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs867468595; called by mutect2, varscan2
- TTC6 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 153/489 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.199); catalogued as rs960159257; called by mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 40/131 reads (31%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.12280C>A p.Q4094K (on ENST00000591111; = p.Q4048K on NM_003319.4) | Missense Mutation (SNP) | VAF 113/386 reads (29%) | catalogued as rs1382977451, COSV100590427; called by mutect2, varscan2
- TTN | c.5645G>A p.R1882H (on ENST00000591111; = p.R1836H on NM_003319.4) | Missense Mutation (SNP) | VAF 114/374 reads (30%) | PolyPhen benign (0.271); catalogued as rs374605213; ClinVar: uncertain significance; called by mutect2, varscan2
- TUB | c.91C>T p.R31W (on ENST00000299506 / NM_177972.3; = p.R86W on NM_003320.4) | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1264205538; called by mutect2, varscan2
- TUBA3C | c.239del p.T80Kfs*13 | Frame Shift Del (DEL) | VAF 46/324 reads (14%) | catalogued as COSV67138896; called by mutect2, pindel, varscan2
- TUSC3 | c.119del p.G40Efs*10 | Frame Shift Del (DEL) | VAF 82/469 reads (17%) | catalogued as COSV65886476; called by mutect2, pindel, varscan2
- UBE3B | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 110/333 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs771722819; called by mutect2, varscan2
- UBR4 | c.12347C>T p.T4116I | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.077); catalogued as rs776416658; called by mutect2, varscan2
- UPF3B | c.1060C>T p.R354* (on ENST00000276201 / NM_080632.3; = p.R341* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 130/396 reads (33%) | catalogued as COSV52232157; called by mutect2, varscan2
- URB1 | c.5693G>A p.R1898H | Missense Mutation (SNP) | VAF 112/428 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1287941853; called by mutect2, varscan2
- USF1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57035524; called by mutect2, varscan2
- USP24 | c.871T>A p.L291I | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV99599288; called by mutect2, varscan2
- USP34 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs1270236572; called by mutect2, varscan2
- USP35 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs762752281; called by mutect2, varscan2
- USP37 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 101/400 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.741); catalogued as rs562303017, COSV51444569, COSV99294011, COSV99294569; called by mutect2, varscan2
- USP38 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs764609696, COSV100189586; called by mutect2, varscan2
- UTRN | c.3737C>T p.T1246I | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV62347415; called by mutect2, varscan2
- VCAN | c.7520C>A p.S2507* | Nonsense Mutation (SNP) | VAF 65/256 reads (25%) | catalogued as rs76091728; called by mutect2, varscan2
- VENTX | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 130/516 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776954774; called by mutect2, varscan2
- VIT | c.1220C>T p.T407M (on ENST00000389975 / NM_001177969.1; = p.T422M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773000051, COSV64896195; called by mutect2, varscan2
- VPS13B | c.5470C>T p.R1824C | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs751912986, COSV104420714, COSV62152331; ClinVar: uncertain significance; called by mutect2, varscan2
- VSIG10L2 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 78/294 reads (27%) | catalogued as rs993924553; called by mutect2, varscan2
- VSTM4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752618813, COSV100039107; called by mutect2, varscan2
- VTN | c.1165C>A p.R389S | Missense Mutation (SNP) | VAF 140/437 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as rs782274235, COSV52646962, COSV99412300; called by mutect2, varscan2
- VWA2 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 124/480 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as rs765092046, COSV53909821; called by mutect2, varscan2
- VWF | c.5287C>T p.R1763W | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs763126601; called by mutect2, varscan2
- VWF | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 143/464 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs756040607, COSV54624209; called by mutect2, varscan2
- WASHC2A | c.1754del p.G585Vfs*51 | Frame Shift Del (DEL) | VAF 59/256 reads (23%) | catalogued as rs1554888524; called by mutect2, varscan2
- WASHC5 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as rs541330058, COSV59195722; called by mutect2, varscan2
- WDFY3 | c.179G>T p.R60M | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55692526; called by mutect2, varscan2
- WDPCP | c.1810A>G p.M604V | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1389225319; called by mutect2, varscan2
- WDR87 | c.4545G>C p.K1515N | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1232428300; called by mutect2, varscan2
- WDTC1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs556572435; called by mutect2, varscan2
- WIPF1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 118/388 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV55810997; called by mutect2, varscan2
- WLS | c.1075del p.V359Yfs*59 | Frame Shift Del (DEL) | VAF 86/306 reads (28%) | catalogued as COSV52047570; called by mutect2, pindel, varscan2
- WSCD1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs564274219; called by mutect2, varscan2
- WWP1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV55356891; called by mutect2, varscan2
- XCR1 | c.287T>G p.V96G | Missense Mutation (SNP) | VAF 122/404 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs745618955; called by mutect2, varscan2
- XIRP2 | c.5912del p.K1971Rfs*8 (on ENST00000628543; = p.K2146Rfs*8 on NM_152381.6) | Frame Shift Del (DEL) | VAF 83/341 reads (24%) | catalogued as COSV54688231; called by mutect2, pindel, varscan2
- XPO4 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 115/381 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs780710707; called by mutect2, varscan2
- XYLT1 | c.343del p.A115Hfs*79 | Frame Shift Del (DEL) | VAF 84/291 reads (29%) | catalogued as rs1555459615, CM064360; called by mutect2, varscan2
- ZBTB7B | c.346G>A p.A116T (on ENST00000292176; = p.A150T on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/444 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs916901424, COSV99421486; called by mutect2, varscan2
- ZC3H12A | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 143/439 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs1222663156, COSV66103969; called by mutect2, varscan2
- ZC3H4 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 86/332 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV53411820; called by mutect2, varscan2
- ZCCHC17 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.47); catalogued as rs144515936; called by mutect2, varscan2
- ZDBF2 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs774520767; called by mutect2, varscan2
- ZDHHC2 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104382534; called by mutect2, varscan2
- ZFP36L2 | c.1408A>G p.S470G | Missense Mutation (SNP) | VAF 138/504 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs929758325; called by mutect2, varscan2
- ZFYVE28 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 94/368 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as rs760996325, COSV99343305; called by mutect2, varscan2
- ZIC1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 119/432 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.139); catalogued as rs1416699660; called by mutect2, varscan2
- ZIC1 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 118/454 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV51555048; called by mutect2, varscan2
- ZIC3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 128/520 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54972605; called by mutect2, varscan2
- ZIM2 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV55625593; called by mutect2, varscan2
- ZMPSTE24 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 106/352 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs747497620, COSV65640201; called by mutect2, varscan2
- ZMYND8 | c.2249C>T p.T750M (on ENST00000311275 / NM_001363741.2; = p.T770M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.411); catalogued as rs1006081568; called by mutect2, varscan2
- ZNF200 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 89/323 reads (28%) | catalogued as rs777457053, COSV67723597; called by mutect2, varscan2
- ZNF208 | c.2432G>A p.G811D | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs755657892; called by mutect2, varscan2
- ZNF236 | c.1381del p.M461* | Frame Shift Del (DEL) | VAF 72/264 reads (27%) | catalogued as rs769237443, COSV53487827; called by mutect2, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 64/272 reads (24%) | catalogued as rs774038489; called by mutect2, varscan2
- ZNF282 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as rs766466237, COSV50479069; called by mutect2, varscan2
- ZNF292 | c.6812C>T p.S2271L | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60535083; called by mutect2, varscan2
- ZNF320 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.431); catalogued as rs532293032, COSV67087984; called by mutect2, varscan2
- ZNF335 | c.3192G>A p.A1064= | Splice Region (SNP) | VAF 87/288 reads (30%) | catalogued as rs369592262; called by mutect2, varscan2
- ZNF385D | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 122/402 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99875267; called by mutect2, varscan2
- ZNF391 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 128/414 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs374426624; called by mutect2, varscan2
1,220 further variants in this file (723 protein-altering or splice-affecting, 429 silent, 68 other) are not listed here.
